Somatic mutation profile of tumor specimen TARGET-30-PASSRN-01A (aliquot TARGET-30-PASSRN-01A-01D) from TARGET case TARGET-30-PASSRN, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 14.6 years (5,345 days).
Specimen TARGET-30-PASSRN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63aa7bee-c010-46c1-886f-61b2c426d55a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASSRN-10A (Blood Derived Normal), aliquot TARGET-30-PASSRN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c72a7260-0866-4c18-8c2a-23837967a00f

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 22, Silent 9, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPVL | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.397); catalogued as COSV55305371; called by muse, mutect2, varscan2
- DNMT3B | c.154A>C p.S52R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.993); catalogued as COSV52420669; called by muse, mutect2, varscan2
- GPRC6A | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV59954642; called by muse, mutect2, varscan2
- GSTA1 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 61/163 reads (37%) | catalogued as COSV58016177; called by muse, mutect2, varscan2
- IRF8 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51899453; called by muse, mutect2, varscan2
- KIAA1109 | c.10943G>A p.R3648H | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs202161647, COSV52683236; called by muse, mutect2, varscan2
- MAML1 | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs904815488, COSV52986608; called by muse, mutect2, varscan2
- MRPL32 | c.344A>G p.H115R | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV56239796; called by muse, mutect2, varscan2
- OR5F1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs534436960, COSV53546798; called by muse, mutect2, varscan2
- PCSK9 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769060209, COSV56163381; called by muse, mutect2, varscan2
- PLEC | c.8925G>T p.E2975D (on ENST00000322810 / NM_201380.4; = p.E2865D on NM_000445.5) | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV59664173; called by muse, mutect2, varscan2
- RALBP1 | c.1455+1G>C p.X485_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV50036977; called by muse, mutect2
- RCL1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 54/113 reads (48%) | catalogued as rs1305915945, COSV67756001; called by muse, mutect2, varscan2
- RSPH4A | c.1055G>T p.R352I | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.185); catalogued as COSV57634630; called by muse, mutect2, varscan2
- SERPINB8 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); catalogued as rs772815370, COSV54640191; called by muse, mutect2, varscan2
- SMG8 | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV56286238; called by muse, mutect2, varscan2
- SND1 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61245019; called by muse, mutect2, varscan2
- SPAG17 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV60463357; called by muse, mutect2, varscan2
- SPATA31E1 | c.704C>A p.A235E | Missense Mutation (SNP) | VAF 81/170 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as COSV57793154, COSV57793571; called by muse, mutect2, varscan2
- THSD7A | c.1385G>T p.R462L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV70264148, COSV70268650; called by muse, mutect2, varscan2
- TMEM63A | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV55302377; called by muse, mutect2, varscan2
- ZNF217 | c.2718C>A p.S906R | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV56600022; called by muse, mutect2, varscan2
- ZNF750 | c.904T>C p.Y302H | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs1255683590; called by muse, mutect2
- ZPBP | c.790A>T p.N264Y | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV50429126; called by muse, varscan2
- TMPRSS11E | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC004922.1 | c.666C>G p.V222= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV53558071; called by muse, mutect2, varscan2
- BICRAL | c.1185C>T p.H395= | Silent (SNP) | VAF 24/355 reads (7%) | catalogued as rs368677077; called by muse, mutect2
- GJB7 | c.489C>A p.P163= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs932768821, COSV51530760; called by muse, mutect2, varscan2
- IGFL3 | c.333C>A p.I111= | Silent (SNP) | VAF 101/191 reads (53%) | catalogued as COSV58243051; called by muse, mutect2, varscan2
- MAK16 | c.726C>T p.A242= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs780244840, COSV62453108; called by mutect2, varscan2
- MCMBP | c.1878A>G p.L626= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV62822535; called by muse, mutect2, varscan2
- MCOLN1 | c.810G>T p.R270= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV51177903; called by muse, mutect2, varscan2
- OR13C4 | c.63C>A p.P21= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV52926778; called by muse, mutect2, varscan2
- OR4D1 | c.378C>A p.I126= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV52125585; called by muse, mutect2, varscan2
